Somatic mutation profile of tumor specimen TCGA-DV-5566-01A (aliquot TCGA-DV-5566-01A-01D-1534-10) from TCGA case TCGA-DV-5566, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 67.7 years (24,717 days).
Specimen TCGA-DV-5566-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7b4cc3d-0067-48b0-86a3-d533af5bb8ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DV-5566-10A (Blood Derived Normal), aliquot TCGA-DV-5566-10A-01D-1535-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5cb3d6f1-5162-4202-8bf3-b280ffcd3cd9

The open-access MAF lists 52 somatic variants for this specimen: 38 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 28, Silent 14, Nonsense Mutation 3, Splice Site 3, Frame Shift Del 2, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB5 | c.354G>T p.L118F | Missense Mutation (SNP) | VAF 65/322 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.159); catalogued as COSV51719992, COSV99327109; called by muse, mutect2, varscan2
- CACNA2D4 | c.157C>T p.L53F | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99764905; called by muse, varscan2
- CD300LF | c.151A>T p.K51* | Nonsense Mutation (SNP) | VAF 31/141 reads (22%) | catalogued as COSV56899380; called by muse, mutect2, varscan2
- CELSR1 | c.8090T>A p.V2697D | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99416387; called by muse, mutect2, varscan2
- CLK4 | c.230G>A p.R77K | Missense Mutation (SNP) | VAF 82/295 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as COSV60321261; called by muse, mutect2, varscan2
- CREB3L2 | c.628C>T p.H210Y | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV57800426; called by muse, mutect2, varscan2
- DAW1 | c.338A>C p.D113A | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59369365; called by muse, mutect2, varscan2
- EMX1 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754890777, COSV50689172; called by muse, mutect2, varscan2
- ENPP2 | c.2183G>T p.R728I (on ENST00000075322 / NM_001040092.3; = p.R780I on NM_006209.5) | Missense Mutation (SNP) | VAF 30/775 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV99307242, COSV99309545; called by muse, mutect2
- ERICH5 | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV59317371; called by muse, mutect2, varscan2
- FLNC | c.3790+1G>A p.X1264_splice | Splice Site (SNP) | VAF 6/15 reads (40%) | catalogued as rs1392170803, COSV100367510; called by muse, mutect2, varscan2
- GYPE | c.221C>G p.S74C | Missense Mutation (SNP) | VAF 52/784 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.526); catalogued as COSV100679126, COSV62261477, COSV62261836; called by muse, mutect2
- IGSF11 | c.898C>A p.H300N (on ENST00000393775 / NM_001015887.3; = p.H299N on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.212); catalogued as COSV61166683, COSV61179118; called by muse, mutect2, varscan2
- IKZF3 | c.420T>A p.H140Q | Missense Mutation (SNP) | VAF 59/235 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53107500; called by muse, mutect2, varscan2
- KRT12 | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV52432552; called by muse, mutect2, varscan2
- KRT6A | c.1550A>G p.Y517C | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); catalogued as COSV58108014; called by muse, mutect2, varscan2
- LMAN1L | c.614G>A p.G205D | Missense Mutation (SNP) | VAF 10/213 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100547509; called by muse, mutect2
- MAN1A1 | c.760A>C p.K254Q | Missense Mutation (SNP) | VAF 121/447 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV63784945; called by muse, mutect2, varscan2
- MAP3K15 | c.2466C>G p.D822E | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.645); catalogued as COSV58839326; called by muse, mutect2, varscan2
- MMP8 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 86/343 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52632910; called by muse, mutect2, varscan2
- MYL1 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 100/416 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV58977012; called by muse, mutect2, varscan2
- NCOR1 | c.2909C>T p.S970L | Missense Mutation (SNP) | VAF 22/370 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as COSV99246453; called by muse, mutect2
- PBRM1 | c.562C>T p.Q188* | Nonsense Mutation (SNP) | VAF 79/201 reads (39%) | catalogued as COSV56269308; called by muse, mutect2, varscan2
- PLG | c.950+1G>T p.X317_splice | Splice Site (SNP) | VAF 20/226 reads (9%) | catalogued as COSV51986692; called by muse, mutect2
- PSKH1 | c.205G>A p.G69S | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV52125075; called by muse, mutect2, varscan2
- PSMA6 | c.94A>C p.I32L | Missense Mutation (SNP) | VAF 97/309 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.229); catalogued as COSV54839292; called by muse, mutect2, varscan2
- QTRT1 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs751857027, COSV51553018; called by muse, mutect2, varscan2
- SLCO1B3 | c.458C>T p.T153I | Missense Mutation (SNP) | VAF 107/419 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV53947098; called by muse, mutect2, varscan2
- SUGT1 | c.519G>A p.K173= (on ENST00000343788 / NM_001130912.3; = p.K141= on NM_006704.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 109/382 reads (29%) | catalogued as rs760001337, COSV59424059; called by muse, mutect2, varscan2
- TM2D2 | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 11/48 reads (23%) | catalogued as COSV65962429; called by muse, mutect2, varscan2
- TNFRSF13B | c.405G>C p.R135S | Missense Mutation (SNP) | VAF 73/273 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.043); catalogued as COSV55430860; called by muse, mutect2, varscan2
- VPS13A | c.2992T>G p.L998V | Missense Mutation (SNP) | VAF 80/276 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62439705; called by muse, mutect2, varscan2
- ZNF606 | c.2034A>T p.K678N | Missense Mutation (SNP) | VAF 73/222 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as COSV58705442, COSV58708170, COSV58708328; called by muse, mutect2, varscan2
- ANKRD6 | c.2085_2089del p.N695Kfs*6 (on ENST00000339746 / NM_001242809.2; = p.N690Kfs*6 on NM_014942.4) | Frame Shift Del (DEL) | VAF 32/123 reads (26%) | called by mutect2, pindel, varscan2
- ELOVL4 | c.156_157insGA p.S53Efs*16 | Frame Shift Ins (INS) | VAF 84/318 reads (26%) | called by mutect2, pindel, varscan2
- HECA | c.1414_1424del p.Q472Yfs*20 | Frame Shift Del (DEL) | VAF 18/83 reads (22%) | called by mutect2, pindel, varscan2
- NBPF20 | c.205T>G p.S69A | Missense Mutation (SNP) | VAF 14/275 reads (5%) | SIFT tolerated (0.81); PolyPhen benign (0.205); called by muse, mutect2
- RPL34 | c.52_65+11del p.X18_splice | Splice Site (DEL) | VAF 67/317 reads (21%) | called by mutect2, pindel, varscan2
- ACO2 | c.978G>A p.L326= | Silent (SNP) | VAF 25/139 reads (18%) | catalogued as rs1475209216, COSV53445647; called by muse, mutect2, varscan2
- ARFGEF3 | c.1707C>T p.V569= | Silent (SNP) | VAF 21/91 reads (23%) | catalogued as COSV52471689; called by muse, mutect2, varscan2
- COL17A1 | c.537C>A p.S179= | Silent (SNP) | VAF 54/163 reads (33%) | catalogued as COSV62229588; called by muse, mutect2, varscan2
- DSN1 | c.1050T>A p.S350= | Silent (SNP) | VAF 90/422 reads (21%) | catalogued as COSV65520310; called by muse, varscan2
- FLNA | c.5070G>T p.T1690= (on ENST00000369850 / NM_001110556.2; = p.T1682= on NM_001456.3) | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV61052406; called by muse, mutect2, varscan2
- GALNT6 | c.933C>G p.P311= | Silent (SNP) | VAF 31/97 reads (32%) | catalogued as COSV62542202, COSV62542435; called by muse, mutect2, varscan2
- IGLV3-1 | c.282C>T p.S94= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs547382671; called by muse, mutect2, varscan2
- PNCK | c.751C>T p.L251= (on ENST00000340888 / NM_001366975.1; = p.L334= on NM_001039582.3) | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV61745625; called by muse, mutect2, varscan2
- PSMA6 | c.93T>C p.A31= | Silent (SNP) | VAF 94/302 reads (31%) | catalogued as COSV99809029; called by muse, varscan2
- PTPRN2 | c.225G>C p.S75= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs376455829, COSV101233434; called by muse, mutect2, varscan2
- RBM15 | c.2868T>C p.F956= | Silent (SNP) | VAF 159/608 reads (26%) | catalogued as COSV63924547; called by muse, mutect2, varscan2
- SACS | c.11073C>T p.F3691= | Silent (SNP) | VAF 68/240 reads (28%) | catalogued as COSV66547100; called by muse, mutect2, varscan2
- SYNE1 | c.24636C>T p.R8212= (on ENST00000367255 / NM_182961.4; = p.R8141= on NM_033071.3) | Silent (SNP) | VAF 43/121 reads (36%) | catalogued as rs886044159, COSV55111810; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF540 | c.1047T>C p.H349= | Silent (SNP) | VAF 62/192 reads (32%) | catalogued as rs544295776, COSV57111580; called by muse, mutect2, varscan2
